TCGA case TCGA-01-0628 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Primary site: Ovary; Tissue source site: International Genomics Consortium.
https://portal.gdc.cancer.gov/cases/f88560c8-3475-47f2-9d48-4b8311bc1132

Biospecimens (1 sample)
- Sample TCGA-01-0628-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 0.4; Intermediate dimension: 0.4; Shortest dimension: 0.4.
